Somatic mutation profile of tumor specimen TCGA-EL-A3MX-01A (aliquot TCGA-EL-A3MX-01A-11D-A21A-08) from TCGA case TCGA-EL-A3MX, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVC; Age at diagnosis: 66.2 years (24,178 days).
Specimen TCGA-EL-A3MX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74394c65-af70-47fe-8f2a-7a3ce26c6783.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3MX-11A (Solid Tissue Normal), aliquot TCGA-EL-A3MX-11A-11D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e68f2a1-90ab-4fbf-a58b-39b816754ac5

The open-access MAF lists 29 somatic variants for this specimen: 23 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 19, Silent 6, Frame Shift Del 2, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ATAD5 | c.3322G>A p.G1108S | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV58979532; called by muse, mutect2, varscan2
- C19orf57 | c.301A>G p.R101G | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV60970433; called by muse, mutect2, varscan2
- COL11A2 | c.2674G>C p.G892R (on ENST00000341947 / NM_080680.3; = p.G785R on NM_080679.2) | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59502934; called by muse, mutect2
- CXCR1 | c.280A>G p.I94V | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.034); catalogued as COSV55283117; called by muse, mutect2, varscan2
- DPH1 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs201983229; called by muse, mutect2, varscan2
- E2F8 | c.2351A>T p.N784I | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV51466315; called by muse, mutect2, varscan2
- ETV5 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as rs201212469, COSV60506991; called by muse, mutect2, varscan2
- FANCM | c.4682T>C p.M1561T | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57506920; called by muse, mutect2
- FER1L6 | c.1228G>T p.A410S | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs761706612, COSV67552934; called by muse, mutect2, varscan2
- GPR101 | c.885G>C p.E295D | Missense Mutation (SNP) | VAF 35/339 reads (10%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); catalogued as COSV53240515; called by muse, mutect2, varscan2
- IMPDH2 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 35/350 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV58247622; called by muse, mutect2, varscan2
- LEMD2 | c.1307A>G p.Y436C | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53394597; called by muse, mutect2, varscan2
- MAP3K3 | c.474dup p.E159Rfs*26 | Frame Shift Ins (INS) | VAF 39/113 reads (35%) | catalogued as rs1208446998; called by mutect2, pindel, varscan2
- MDN1 | c.14927C>T p.S4976F | Missense Mutation (SNP) | VAF 17/191 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV65530731; called by muse, mutect2
- NRXN1 | c.4172C>G p.A1391G | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV60521950, COSV60524160; called by muse, mutect2, varscan2
- OGFOD1 | c.865del p.E289Kfs*7 | Frame Shift Del (DEL) | VAF 6/47 reads (13%) | catalogued as COSV60200613; called by mutect2, pindel, varscan2
- STAC3 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 16/342 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as COSV60416296; called by muse, mutect2
- TBC1D22B | c.29G>A p.W10* | Nonsense Mutation (SNP) | VAF 13/66 reads (20%) | catalogued as COSV60827112; called by muse, mutect2, varscan2
- TRIO | c.1109T>C p.I370T | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs1440979630, COSV60096681; called by muse, mutect2, varscan2
- VAMP3 | c.223A>T p.N75Y | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV50012969; called by muse, mutect2, varscan2
- ZNF709 | c.115A>G p.N39D | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67196006; called by muse, varscan2
- HELZ2 | c.2212del p.V738Sfs*62 (on ENST00000467148 / NM_001037335.2; = p.V169Sfs*62 on NM_033405.3) | Frame Shift Del (DEL) | VAF 28/100 reads (28%) | called by mutect2, pindel, varscan2
- DHX32 | c.726T>C p.P242= | Silent (SNP) | VAF 20/130 reads (15%) | catalogued as COSV52943570; called by muse, mutect2, varscan2
- HIBADH | c.789G>T p.V263= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV55312298; called by muse, mutect2
- LYAR | c.714C>T p.V238= | Silent (SNP) | VAF 139/304 reads (46%) | catalogued as COSV58642277; called by muse, mutect2, varscan2
- PHLDB2 | c.2763C>T p.I921= (on ENST00000393925 / NM_001134439.2; = p.I878= on NM_145753.2) | Silent (SNP) | VAF 20/97 reads (21%) | catalogued as COSV67316375; called by muse, mutect2, varscan2
- TEP1 | c.2043C>G p.V681= | Silent (SNP) | VAF 24/235 reads (10%) | catalogued as COSV53000669; called by muse, mutect2, varscan2
- ZNF554 | c.204C>T p.N68= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as COSV57887100; called by muse, mutect2, varscan2
